Somatic mutation profile of tumor specimen TCGA-CD-8529-01A (aliquot TCGA-CD-8529-01A-11D-2340-08) from TCGA case TCGA-CD-8529, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.7 years (23,979 days).
Specimen TCGA-CD-8529-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77d24ac6-2fec-402b-8479-de2ff1d37c21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8529-10A (Blood Derived Normal), aliquot TCGA-CD-8529-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f17e6cc-f97a-43b3-8f0e-6fdcee66489f

The open-access MAF lists 427 somatic variants for this specimen: 320 protein-altering or splice-affecting, 99 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 99, Nonsense Mutation 15, Frame Shift Del 12, Splice Site 4, In Frame Del 4, Intron 3, RNA 3, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.3263del p.P1088Lfs*16 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs80359379, COSV101204458; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.2689C>G p.L897V (on ENST00000272895 / NM_173076.3; = p.L579V on NM_015657.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV55977417; called by muse, mutect2, varscan2
- ABRA | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV61733757; called by muse, mutect2
- ADCK1 | c.1122C>A p.Y374* | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as rs1321787728; called by muse, mutect2
- ADHFE1 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs755425165, COSV52554327, COSV52559496; called by muse, mutect2, varscan2
- ADHFE1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs766239380, COSV52558353; called by muse, mutect2, varscan2
- AFF3 | c.2956C>G p.R986G | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57854798, COSV57875429; called by muse, mutect2
- AHNAK2 | c.5363G>A p.S1788N | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV60932324; called by muse, mutect2
- AL592490.1 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV69428177; called by muse, mutect2, varscan2
- AMPD3 | c.778C>T p.H260Y (on ENST00000396553 / NM_001025389.2; = p.H269Y on NM_000480.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV67332714; called by muse, mutect2, varscan2
- AMPH | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57758870; called by muse, mutect2, varscan2
- ANKRD27 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as COSV60136459, COSV60136487; called by muse, mutect2
- ARHGAP5 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV61539549; called by muse, mutect2
- ASPH | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1165452346, COSV65248067; called by muse, mutect2
- ATG4D | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.061); catalogued as COSV58763879; called by muse, mutect2
- ATP2B2 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1405062514, COSV59506056; called by muse, mutect2
- AXL | c.1456G>C p.E486Q (on ENST00000301178 / NM_021913.5; = p.E477Q on NM_001699.6) | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV56575687; called by muse, mutect2
- B4GAT1 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV60820813; called by muse, mutect2
- BCL7C | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs188345023; called by muse, mutect2, varscan2
- BICRAL | c.1503G>C p.L501F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV58408717; called by muse, mutect2
- BRD3 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV57706990; called by muse, mutect2, varscan2
- BRINP3 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV66542684; called by muse, mutect2, varscan2
- BSN | c.11258C>A p.A3753D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56528639; called by muse, mutect2
- BTBD16 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs376150771; called by muse, mutect2
- BUB1 | c.3222T>G p.I1074M | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV57067555; called by muse, mutect2
- C6 | c.1430A>G p.K477R | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV54719786; called by muse, mutect2
- C6orf118 | c.199A>G p.N67D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV57819942; called by muse, mutect2, varscan2
- CALM2 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55400645; called by muse, mutect2, varscan2
- CAMSAP2 | c.3372T>G p.I1124M (on ENST00000236925 / NM_001297707.2; = p.I1113M on NM_203459.3) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52678387; called by muse, mutect2, varscan2
- CASS4 | c.2009C>A p.P670H | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64388635; called by muse, mutect2
- CCAR1 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56275100; called by muse, mutect2
- CCNL1 | c.1002T>G p.F334L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as COSV55819578; called by muse, mutect2, varscan2
- CD2BP2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV59769962; called by mutect2, varscan2
- CD72 | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV52412192, COSV52412541; called by muse, mutect2
- CDC6 | c.963T>A p.D321E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52931566; called by muse, mutect2
- CDH10 | c.521T>A p.V174D | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52599825; called by muse, mutect2
- CENPF | c.978A>T p.K326N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV65279498; called by muse, mutect2, varscan2
- CFAP65 | c.2091G>A p.W697* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV58562328, COSV58566815; called by muse, mutect2
- CHAT | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs994328519, COSV60334006; called by muse, mutect2, varscan2
- CHD6 | c.5891T>G p.I1964S | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV64694935; called by muse, mutect2
- CNGB1 | c.3199G>A p.V1067M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51907712; called by muse, mutect2, varscan2
- CNP | c.1241C>G p.A414G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57270582; called by muse, mutect2, varscan2
- COL1A1 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56804393; called by muse, mutect2
- COL6A6 | c.3601C>A p.Q1201K | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV62026733, COSV62039005; called by muse, mutect2
- CRNKL1 | c.1147G>C p.A383P | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66107260; called by muse, mutect2
- CUL9 | c.4883G>A p.R1628H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs749507027, COSV52726447; called by mutect2, varscan2
- CYLD | c.1413A>T p.E471D | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61097640; called by muse, mutect2, varscan2
- CYP2F1 | c.151A>C p.M51L | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58528968; called by muse, mutect2, varscan2
- DCAF17 | c.1521T>G p.C507W | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59831213; called by muse, mutect2, varscan2
- DDX17 | c.1370G>C p.R457T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53256762; called by muse, mutect2
- DDX6 | c.753G>C p.L251F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50592659; called by muse, mutect2
- DGKK | c.1256G>C p.C419S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65709539; called by muse, mutect2, varscan2
- DIMT1 | c.447G>A p.R149= | Splice Region (SNP) | VAF 14/75 reads (19%) | catalogued as COSV52235116; called by muse, mutect2, varscan2
- DIP2A | c.503A>T p.D168V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV59487887; called by muse, mutect2
- DKK2 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53404071; called by muse, mutect2, varscan2
- DLX1 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV59395423; called by muse, mutect2
- DNAH3 | c.10658C>G p.S3553C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54508611, COSV54555645; called by muse, mutect2, varscan2
- DNAH3 | c.6616C>G p.H2206D | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54555674; called by muse, mutect2
- DNAH3 | c.5221G>C p.V1741L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54555700; called by muse, mutect2, varscan2
- DNAH8 | c.11021T>C p.I3674T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59483705; called by muse, mutect2
- DOK6 | c.409+1G>T p.X137_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101234491, COSV101235036; called by muse, mutect2
- DOP1A | c.6134T>G p.L2045W | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52719000; called by muse, mutect2
- DSG4 | c.484T>G p.Y162D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV57398253; called by muse, mutect2, varscan2
- DYNC1H1 | c.8799G>C p.L2933F | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64143366; called by muse, mutect2
- ECM2 | c.2040C>G p.Y680* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV60743117; called by muse, mutect2
- EGFLAM | c.1041T>G p.C347W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59319194; called by muse, mutect2, varscan2
- EIF1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV60423040; called by muse, mutect2, varscan2
- EVI2B | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV58365172; called by muse, mutect2, varscan2
- F5 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs1330761400, COSV63128943; called by muse, mutect2, varscan2
- FAM114A2 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV61078858; called by muse, mutect2, varscan2
- FAM120A | c.2213C>G p.A738G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52905341, COSV52911732; called by muse, mutect2, varscan2
- FASLG | c.803A>T p.N268I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV60681074; called by muse, mutect2, varscan2
- FCRL3 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs916330622, COSV63845343; called by muse, mutect2
- FER1L6 | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs367553708, COSV67550122; called by muse, mutect2, varscan2
- FKBP1A | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67750755; called by muse, mutect2, varscan2
- FKTN | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.201); catalogued as rs1389073650, COSV56312413; called by muse, mutect2
- FREM1 | c.489T>G p.Y163* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV66530929; called by muse, mutect2
- FREM2 | c.2949C>G p.F983L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV54854113; called by muse, mutect2
- FURIN | c.1694A>C p.K565T | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV51580009; called by muse, mutect2
- FUT5 | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV53139087; called by muse, mutect2, varscan2
- GABRA2 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100734860; called by muse, mutect2, varscan2
- GABRA2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100734447, COSV100734861; called by muse, mutect2, varscan2
- GALNT10 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780564646, COSV51720121; called by muse, mutect2
- GFRA1 | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV62603665, COSV62611345; called by muse, mutect2, varscan2
- GID8 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV56612402; called by muse, mutect2
- GNA13 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV71475278; called by muse, mutect2, varscan2
- GPRC5D | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV57433578; called by muse, mutect2
- GPRIN3 | c.548A>C p.D183A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV60886586; called by muse, mutect2
- GPSM2 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51443160; called by muse, mutect2
- GXYLT1 | c.1039A>T p.I347L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV55143238; called by muse, mutect2, varscan2
- HBEGF | c.491C>G p.A164G | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV50183475; called by muse, mutect2, varscan2
- HCFC1 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV60078221; called by muse, mutect2, varscan2
- HDDC3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV57746908; called by muse, mutect2
- HELQ | c.2840A>T p.E947V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV55028247; called by muse, mutect2
- HMGCLL1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV51451827; called by muse, mutect2
- HTT | c.5260G>C p.D1754H | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.651); catalogued as COSV61870281; called by muse, mutect2, varscan2
- IFNAR2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59751663; called by muse, mutect2
- IFNGR1 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.188); catalogued as COSV62990431; called by muse, mutect2
- IFTAP | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57557899; called by muse, mutect2
- IGBP1P2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs780486847, COSV53614767; called by muse, mutect2
- IK | c.1054A>G p.R352G | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV70258296; called by muse, mutect2
- IL3RA | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58433538; called by muse, mutect2
- IMPA2 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV52321776; called by muse, mutect2, varscan2
- INPP5K | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV57443033; called by muse, mutect2
- INSL6 | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV67562990, COSV67563534; called by muse, mutect2
- INTS11 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325699635; called by muse, mutect2
- IQCD | c.1144G>C p.E382Q (on ENST00000416617 / NM_001330452.2; = p.E280Q on NM_138451.3) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55323904; called by muse, mutect2
- ITGAD | c.1819G>C p.G607R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV66760481; called by muse, mutect2, varscan2
- ITPRID2 | c.407A>T p.N136I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV57476931; called by muse, mutect2, varscan2
- KAT2B | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55435095; called by muse, mutect2
- KAZN | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs147538261; called by muse, mutect2, varscan2
- KCND3 | c.183C>G p.Y61* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56190490; called by muse, mutect2
- KHDC4 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64165908; called by muse, mutect2
- KIAA0232 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV56929803; called by muse, mutect2
- KIAA0825 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV56947906; called by muse, mutect2
- KIF15 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs747160107, COSV58163245; called by muse, mutect2
- KIF22 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV50719475; called by muse, mutect2
- KMT2C | c.7529T>C p.V2510A | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV104384004, COSV51507983; called by muse, mutect2
- KMT2C | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV51508004; called by muse, mutect2, varscan2
- KRT16 | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV56969933; called by muse, mutect2
- KRT19 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64239437; called by muse, mutect2
- KRTAP10-12 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV59981808; called by muse, mutect2
- LAMB1 | c.4342G>T p.D1448Y | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV55970784, COSV99741868; called by muse, mutect2, varscan2
- LIPH | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV99955696; called by muse, mutect2
- LPAR1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779129771, COSV62687652; called by muse, mutect2, varscan2
- LRFN3 | c.620C>A p.A207D | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV55819222; called by muse, mutect2
- LRRC4 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV50813376; called by muse, mutect2
- LRRC43 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100336763, COSV60289516, COSV60293688; called by mutect2, varscan2
- LRRC8B | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV58377469; called by muse, mutect2
- LTBP4 | c.2377G>A p.E793K (on ENST00000308370 / NM_001042544.1; = p.E756K on NM_003573.2) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs199691160, COSV52591463; called by mutect2, varscan2
- LYST | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67714827; called by muse, mutect2
- MACF1 | c.4864G>C p.D1622H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | catalogued as COSV57146450; called by muse, mutect2, varscan2
- MAK | c.988C>G p.Q330E | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV57567992; called by muse, mutect2
- MCM8 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV52545827; called by muse, mutect2, varscan2
- MED13L | c.3757A>T p.T1253S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56131225; called by muse, mutect2, varscan2
- MKRN3 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV58812440; called by muse, mutect2
- MRPL1 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1449115137, COSV59676995; called by muse, mutect2
- MTFMT | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as COSV54980092; called by muse, mutect2
- MUC16 | c.38896A>T p.S12966C | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV67497061; called by muse, mutect2
- MUC16 | c.35207C>T p.S11736L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67497064; called by muse, mutect2, varscan2
- MYCBP2 | c.11609A>C p.Q3870P (on ENST00000357337; = p.Q3908P on NM_015057.5) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62041138; called by muse, mutect2
- MYCBP2 | c.1750C>T p.R584W (on ENST00000357337; = p.R622W on NM_015057.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs369757801; called by muse, mutect2, varscan2
- MYH15 | c.4002G>T p.E1334D | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV56320904; called by muse, mutect2, varscan2
- MYLK3 | c.2011G>C p.V671L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV67367115; called by muse, mutect2
- MYLK4 | c.952T>G p.C318G | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV51153866; called by muse, varscan2
- MYO1B | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV58438732; called by muse, mutect2
- MYO1F | c.2411del p.G804Afs*7 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV57797349; called by mutect2, pindel
- MYOCD | c.1013C>A p.S338* | Nonsense Mutation (SNP) | VAF 13/166 reads (8%) | catalogued as COSV58513189; called by muse, mutect2
- NAA30 | c.726T>A p.Y242* | Nonsense Mutation (SNP) | VAF 35/315 reads (11%) | catalogued as COSV53649864; called by muse, mutect2, varscan2
- NEU1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs779431356, COSV57669330; called by muse, mutect2
- NFE2L1 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62583841; called by muse, mutect2
- NLRP14 | c.304A>C p.I102L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55072663; called by muse, mutect2
- NLRP14 | c.1169C>A p.T390K | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV55072676; called by muse, mutect2
- NMUR2 | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV54922927; called by muse, mutect2
- NOVA2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54360223; called by muse, mutect2
- NSDHL | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV64745439; called by muse, mutect2, varscan2
- NYX | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61181005; called by muse, mutect2
- OPN3 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59366553; called by muse, mutect2, varscan2
- OR10P1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV59008184; called by muse, mutect2
- OR1G1 | c.580A>C p.T194P | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61030673; called by muse, mutect2
- OR1L1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.322); catalogued as COSV58936858; called by muse, mutect2, varscan2
- OR2L3 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63456441; called by muse, mutect2
- OR4K1 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53459694, COSV53462912; called by muse, mutect2
- OR56B1 | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV57724054; called by muse, mutect2
- OR9Q1 | c.69G>C p.W23C | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV59048023; called by muse, mutect2, varscan2
- OXA1L | c.87A>T p.Q29H | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.66); catalogued as rs1202683750, COSV53538611; called by muse, mutect2
- PABPC1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100589951; called by muse, mutect2
- PAN2 | c.1842G>C p.Q614H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57756306; called by muse, mutect2
- PARVG | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV63563068; called by muse, mutect2
- PAX6 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV53795263; called by muse, mutect2, varscan2
- PCDH15 | c.1168A>T p.N390Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57402638; called by muse, mutect2, varscan2
- PCDHA4 | c.680A>C p.Q227P | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs782786124, COSV63546608; called by muse, mutect2, varscan2
- PCDHA5 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.104); catalogued as COSV65358459; called by muse, mutect2
- PCDHGA12 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); catalogued as COSV52771133; called by muse, mutect2, varscan2
- PCDHGA8 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV53930877, COSV54050040; called by muse, mutect2, varscan2
- PCDHGC4 | c.47C>A p.T16N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52771147; called by muse, mutect2, varscan2
- PDIA2 | c.662_663del p.V221Gfs*7 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as rs868281531; called by pindel, varscan2
- PDXDC1 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57912513; called by muse, mutect2
- PHF24 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs754208132, COSV54273124; called by muse, mutect2
- PHOSPHO2 | c.589A>T p.M197L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV55869961; called by muse, mutect2, varscan2
- PIGG | c.2806G>T p.V936F (on ENST00000453061 / NM_001127178.3; = p.V928F on NM_017733.4) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV56317620, COSV56321817; called by muse, mutect2
- PKD2L1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV58399207; called by muse, mutect2
- PKHD1L1 | c.10366G>T p.A3456S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV65754444; called by muse, mutect2
- PMS1 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377603311; called by muse, mutect2, varscan2
- PODN | c.848A>T p.H283L (on ENST00000395871; = p.H235L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV57017815; called by muse, mutect2
- POLD1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs201804732, COSV101486911, COSV70957727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.1287T>A p.F429L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV57285133; called by muse, mutect2, varscan2
- PPP1R2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.06); catalogued as COSV60498685; called by muse, mutect2
- PPP2R2A | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60099378; called by muse, mutect2
- PRKDC | c.1081A>G p.I361V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1484606220, COSV58065359; called by muse, mutect2
- PRPH2 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57838620; called by muse, mutect2
- PSG7 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.753); catalogued as COSV68444276; called by muse, mutect2, varscan2
- PSMA6 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV54839334; called by muse, mutect2, varscan2
- PSMF1 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55676412; called by muse, mutect2
- PTER | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs376388470; called by muse, mutect2, varscan2
- PTGS2 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV66571981; called by muse, mutect2
- PTPRT | c.3046A>G p.I1016V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.114); catalogued as COSV62025930; called by muse, mutect2
- RANBP2 | c.8179G>C p.D2727H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV51709451; called by muse, mutect2
- RAP1GAP2 | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV54581646; called by muse, mutect2
- RELB | c.1535C>G p.A512G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV55513160; called by muse, mutect2
- REM1 | c.195T>A p.D65E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52430302; called by muse, mutect2, varscan2
- RGS18 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.49); catalogued as COSV66510220; called by muse, mutect2, varscan2
- RIF1 | c.4478C>G p.T1493S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.053); catalogued as COSV54625088; called by muse, mutect2, varscan2
- RIMS2 | c.2050A>T p.I684L (on ENST00000666250 / NM_001348490.2; = p.I492L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV51728077; called by muse, mutect2, varscan2
- RRM1 | c.2158C>G p.L720V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as COSV56166463; called by muse, mutect2, varscan2
- RTCA | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV53122541; called by muse, mutect2
- RYR1 | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62112259; called by muse, mutect2, varscan2
- SBF2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56312913; called by muse, mutect2, varscan2
- SCIN | c.1496C>G p.S499* (on ENST00000297029 / NM_001112706.3; = p.S252* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV51699409; called by muse, mutect2
- SCN11A | c.1221C>G p.N407K | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV56579224; called by muse, mutect2
- SCN2A | c.2790C>A p.H930Q | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51856787; called by muse, mutect2, varscan2
- SCN3A | c.2421G>C p.M807I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51825823; called by muse, mutect2, varscan2
- SCYL1 | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54216121; called by muse, mutect2, varscan2
- SDHAF4 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65085555; called by muse, mutect2
- SEC23A | c.2012G>C p.G671A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56979296; called by muse, mutect2, varscan2
- SEC24A | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV59750087; called by muse, mutect2
- SELP | c.1028C>A p.A343D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs764864800, COSV55259126; called by muse, mutect2, varscan2
- SERPINE1 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV56170815, COSV56171791; called by muse, mutect2, varscan2
- SH3BGRL2 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV63965540, COSV63965614; called by muse, mutect2
- SHC3 | c.1667A>G p.K556R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV65447446; called by muse, mutect2
- SLC11A1 | c.908T>C p.M303T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs138751863; called by mutect2, varscan2
- SLC26A8 | c.1702T>G p.Y568D | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV62887855; called by muse, mutect2, varscan2
- SLC30A8 | c.778T>A p.L260M | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV69974482, COSV69976771; called by muse, mutect2
- SLC6A16 | c.1227G>C p.E409D | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV60030814; called by muse, mutect2
- SLCO4C1 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV60520606; called by mutect2, varscan2
- SMG8 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1480881546, COSV56287308; called by muse, mutect2
- SPPL2A | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV55943415; called by muse, mutect2, varscan2
- SPTA1 | c.7236C>A p.F2412L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63524935, COSV63526642; called by muse, mutect2, varscan2
- SPTAN1 | c.7126G>A p.D2376N | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.31); catalogued as rs1436043063, COSV63990058; called by muse, mutect2
- SRCIN1 | c.1724C>T p.S575L (on ENST00000621492; = p.S541L on NM_025248.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.072); catalogued as rs756455679; called by muse, mutect2, varscan2
- ST6GAL2 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | PolyPhen possibly damaging (0.459); catalogued as COSV64532206; called by muse, mutect2, varscan2
- STAB2 | c.6736G>C p.A2246P | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV66347964; called by muse, mutect2
- STT3B | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as rs1455933205, COSV55506291; called by muse, mutect2, varscan2
- STUB1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs764534080, COSV50198343; called by muse, mutect2, varscan2
- SV2A | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | catalogued as COSV64966075; called by muse, mutect2
- TAX1BP1 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV55297327; called by muse, mutect2, varscan2
- TCF7L2 | c.530C>A p.S177Y (on ENST00000355995 / NM_001367943.1; = p.S154Y on NM_030756.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60511994; called by muse, mutect2, varscan2
- TFF3 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs780786070, COSV52295151; called by muse, mutect2, varscan2
- THEM5 | c.563T>A p.I188N | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64313270; called by muse, mutect2, varscan2
- THRA | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV52846638; called by muse, mutect2
- TIE1 | c.2552G>T p.G851V | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65251612; called by muse, mutect2
- TIPRL | c.605A>C p.Y202S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63208188; called by muse, mutect2
- TLL1 | c.924G>C p.M308I | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.087); catalogued as COSV50271620, COSV50330032; called by muse, mutect2
- TLN1 | c.6031A>T p.T2011S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59212116; called by muse, varscan2
- TM9SF3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV64458790; called by muse, mutect2, varscan2
- TMC5 | c.1540C>A p.Q514K (on ENST00000396229 / NM_001105248.1; = p.Q268K on NM_024780.5) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54910451; called by muse, mutect2, varscan2
- TMEM38B | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV65951640; called by muse, mutect2
- TMTC4 | c.1637+1G>T p.X546_splice (on ENST00000376234 / NM_001350577.2; = p.X565_splice on NM_032813.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 26/67 reads (39%) | catalogued as COSV60893749; called by muse, mutect2, varscan2
- TNNC2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs1246522904, COSV65333321; called by muse, mutect2
- TNS1 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50776149; called by muse, mutect2, varscan2
- TRPC4AP | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.931); catalogued as COSV52684904; called by muse, mutect2
- TSPAN18 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751020111, COSV60887975; called by muse, mutect2, varscan2
- TTC30A | c.1989G>C p.W663C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV63102447; called by muse, mutect2
- TTLL5 | c.2791C>G p.Q931E | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.103); catalogued as COSV54045074; called by muse, mutect2, varscan2
- UNC79 | c.5263G>A p.A1755T (on ENST00000393151 / NM_001346218.2; = p.A1578T on NM_020818.5) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.542); catalogued as rs1288559528, COSV56413604, COSV99826572; called by muse, mutect2, varscan2
- USH2A | c.12731A>G p.N4244S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV56445156; called by muse, mutect2, varscan2
- VARS2 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV52561417; called by muse, mutect2
- VIM | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs116370722, COSV56406520; called by muse, varscan2
- VPS13B | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62026554; called by muse, mutect2
- WBP2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs549580393, COSV52882997; called by mutect2, varscan2
- WHRN | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV54335303; called by muse, mutect2
- WIPF2 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60276172; called by mutect2, varscan2
- WWP2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as COSV63128169; called by muse, mutect2
- XRN1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV53818794; called by muse, mutect2
- XRN2 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV65871795; called by muse, mutect2, varscan2
- ZBED9 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV101509348, COSV71729804; called by muse, mutect2
- ZDHHC8 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV57713268; called by muse, mutect2, varscan2
- ZFYVE26 | c.5790G>T p.Q1930H | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV61334016; called by muse, mutect2
- ZKSCAN5 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58744787; called by muse, mutect2, varscan2
- ZNF320 | c.1349T>C p.F450S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67089085; called by muse, mutect2
- ZNF473 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as COSV54525308; called by muse, mutect2, varscan2
- ZNF615 | c.1424A>C p.Q475P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1182157822, COSV65035119; called by muse, mutect2, varscan2
- ZNF665 | c.1383T>A p.H461Q (on ENST00000600412; = p.H526Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67217839; called by muse, mutect2
- ZNF793 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV71325208, COSV71325211; called by muse, mutect2, varscan2
- ZNF883 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV71308942, COSV71309270; called by muse, mutect2
- ZSCAN18 | c.1012C>G p.P338A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.539); catalogued as COSV53737835; called by muse, mutect2, varscan2
- ADGRA2 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGRL4 | c.1500del p.L502* | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel, varscan2
- AKAP4 | c.1828_1850del p.S610Tfs*22 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel
- ANXA8L1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- APPL1 | c.1611C>G p.I537M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- BHLHE40 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDRT1 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | PolyPhen probably damaging (0.959); called by muse, mutect2
- CEP112 | c.649A>T p.N217Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP152 | c.3385G>T p.G1129C | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- COL12A1 | c.8578-16_8594del p.X2860_splice | Splice Site (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CRTC2 | c.2038G>C p.D680H | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSHL1 | c.514C>G p.Q172E (on ENST00000309894 / NM_022581.3; = p.Q78E on NM_001318.4) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2
- CSTL1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- CTSB | c.804del p.Q268Hfs*7 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DCBLD1 | c.1234del p.C412Afs*43 | Frame Shift Del (DEL) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- EEF2 | c.1333A>C p.K445Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXL3 | c.1181_1206del p.E394Vfs*2 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- HMG20A | c.1023_1025del p.V342del | In Frame Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- IFI16 | c.332C>G p.T111R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- KCNK16 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MAST2 | c.2222A>C p.E741A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, varscan2
- MBTPS1 | c.2477_2501del p.P826Qfs*41 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel
- MUC3A | c.8555C>G p.T2852S | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- NOTCH4 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- OR13H1 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OR2B6 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PARP1 | c.2215del p.L739* | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- PEG3 | c.1348_1390del p.M450Sfs*115 | Frame Shift Del (DEL) | VAF 28/234 reads (12%) | called by mutect2, pindel
- POLA1 | c.611C>A p.S204* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- PYHIN1 | c.298_316del p.G100Rfs*90 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- RAP1GAP2 | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- SCLT1 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SCN11A | c.965G>C p.C322S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN11A | c.964T>G p.C322G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC12A7 | c.1799C>A p.T600N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SLCO4A1 | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- SYCP2L | c.361_363del p.T121del | In Frame Del (DEL) | VAF 8/86 reads (9%) | called by pindel, varscan2
- TEX11 | c.1569_1574del p.D523_E524del (on ENST00000344304; = p.D508_E509del on NM_031276.3) | In Frame Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.3815G>T p.R1272M | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNKS1BP1 | c.3814A>G p.R1272G | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); called by muse, mutect2
- UGT3A2 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF165 | c.973_1008del p.S325_A336del | In Frame Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- ZNF568 | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- ABCC11 | c.3333A>T p.I1111= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV62326148; called by muse, mutect2
- AC011462.1 | c.108A>G p.R36= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV60532395; called by muse, mutect2, varscan2
- ADRA1A | c.933A>C p.V311= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV52375209; called by muse, mutect2
- AMBRA1 | c.3462G>T p.L1154= (on ENST00000458649 / NM_001367468.1; = p.L1064= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54063351; called by muse, mutect2
- AMER2 | c.1938C>T p.V646= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV63440546; called by muse, mutect2
- ANKRD55 | c.306C>T p.T102= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV61951129; called by muse, mutect2
- ARHGAP21 | c.4416C>T p.I1472= | Silent (SNP) | VAF 24/213 reads (11%) | catalogued as COSV57611675; called by muse, mutect2, varscan2
- ARHGEF2 | c.393G>A p.R131= (on ENST00000361247 / NM_001162383.2; = p.R104= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV58117708; called by muse, mutect2, varscan2
- ATP7A | c.2115T>C p.I705= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as COSV58454841; called by muse, mutect2, varscan2
- ATR | c.5478G>A p.V1826= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- BLCAP | c.90C>G p.G30= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV50351771; called by muse, mutect2
- CACNA2D4 | c.465C>T p.H155= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs752053429, COSV54962077; called by muse, mutect2, varscan2
- CASP4 | c.105G>A p.L35= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV67744935; called by muse, mutect2, varscan2
- CEP164 | c.2031C>G p.V677= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs761278682, COSV54046810; called by muse, mutect2, varscan2
- CLDN10 | c.189G>A p.P63= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV65300122; called by muse, mutect2, varscan2
- CLTCL1 | c.2460T>G p.L820= | Silent (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- CNGA3 | c.1593T>A p.A531= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV55628635; called by muse, mutect2
- CNOT1 | c.6318C>T p.F2106= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55322820; called by muse, mutect2, varscan2
- COL4A1 | c.3337C>T p.L1113= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV65432624; called by muse, mutect2
- CP | c.2541T>A p.T847= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV52834465; called by muse, mutect2
- CSMD3 | c.10212T>A p.P3404= (on ENST00000297405 / NM_001363185.1; = p.P3235= on NM_052900.3) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV52148131, COSV52332915; called by muse, mutect2
- DLGAP4 | c.459G>A p.K153= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV59424074; called by muse, mutect2
- DNAH9 | c.8082G>A p.V2694= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV52357018, COSV52378953; called by muse, mutect2, varscan2
- DOLK | c.888C>T p.T296= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV58282889; called by muse, mutect2
- DYNC1H1 | c.12897C>A p.G4299= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV64143374; called by muse, mutect2, varscan2
- EDRF1 | c.1080C>T p.C360= (on ENST00000356792 / NM_001202438.2; = p.C326= on NM_015608.2) | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV61766472; called by muse, mutect2
- ENPEP | c.315C>T p.H105= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs1242332621, COSV54458101, COSV99487992; called by muse, mutect2, varscan2
- ERCC6L | c.3327C>T p.D1109= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV57822552; called by muse, mutect2, varscan2
- ESRRG | c.1195C>T p.L399= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs745321895, COSV63183019; called by muse, mutect2, varscan2
- FAM13C | c.718C>A p.R240= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1444709447; called by muse, mutect2
- FCGBP | c.5271C>T p.N1757= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs1342400530; called by muse, mutect2, varscan2
- FERMT1 | c.807C>G p.L269= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54098067; called by mutect2, varscan2
- FTO | c.1374A>G p.S458= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV51669058; called by muse, mutect2, varscan2
- GFRA3 | c.198C>A p.S66= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV51231978; called by muse, mutect2, varscan2
- GK | c.225T>G p.L75= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- GRIN2A | c.2232C>T p.G744= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV58058123; called by muse, mutect2
- GRM1 | c.684T>C p.S228= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs763027569, COSV51366669; called by muse, mutect2
- HGF | c.600C>A p.V200= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV55957837; called by muse, mutect2
- HGFAC | c.774G>A p.L258= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100122601, COSV58757699; called by muse, mutect2, varscan2
- IGLV11-55 | c.336T>C p.D112= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- ITGAX | c.1908G>A p.A636= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs773833533, COSV51652155, COSV99191928; called by muse, mutect2, varscan2
- JCHAIN | c.450C>G p.A150= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV54660106; called by muse, mutect2
- KANK1 | c.1839C>T p.L613= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs957457141, COSV63216637; called by muse, mutect2
- KDR | c.771C>T p.D257= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV55777431; called by muse, mutect2
- KRT12 | c.1038C>T p.T346= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV52430615; called by muse, mutect2
- KRT20 | c.345C>T p.R115= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs754052121, COSV51426351; called by muse, mutect2
- KRTAP12-3 | c.171C>T p.P57= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs587661101, COSV59981799; called by muse, mutect2
- LRR1 | c.387A>G p.S129= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV53565183; called by muse, mutect2
- MAP3K6 | c.1029G>A p.Q343= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV62890306; called by muse, mutect2, varscan2
- MATN4 | c.147G>A p.E49= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV59216015; called by muse, mutect2, varscan2
- MED23 | c.1104C>G p.G368= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV63437759; called by muse, mutect2
- MLH3 | c.3111A>G p.S1037= | Silent (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- MR1 | c.915C>G p.V305= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV51582342; called by muse, mutect2, varscan2
- MTFMT | c.402T>C p.L134= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV54980072; called by muse, mutect2
- MUC16 | c.8883C>A p.T2961= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs1050627555, COSV101202281; called by muse, mutect2
- NDUFB4 | c.69C>T p.Y23= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs749905815, COSV51743043; called by mutect2, varscan2
- NELL1 | c.1533C>T p.N511= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs775236513, COSV54331191; called by muse, mutect2, varscan2
- NFATC4 | c.1719G>A p.V573= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV51612742; called by muse, mutect2, varscan2
- NME7 | c.549G>A p.V183= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV63171117; called by muse, mutect2, varscan2
- NRXN1 | c.3570G>A p.K1190= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV60525191; called by muse, mutect2
- OPA3 | c.360C>T p.N120= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1308359391, COSV54400771; called by muse, mutect2, varscan2
- OR10H1 | c.477G>C p.V159= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV58473214; called by muse, mutect2
- OR10K1 | c.513C>A p.S171= | Silent (SNP) | VAF 20/380 reads (5%) | catalogued as COSV56874509; called by muse, mutect2
- OR5AR1 | c.726G>T p.G242= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV57255500; called by muse, mutect2, varscan2
- OR5K4 | c.717T>A p.S239= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV61584420; called by muse, mutect2
- OR5M1 | c.555C>T p.I185= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV101591551; called by muse, mutect2
- PAX6 | c.828A>G p.R276= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV53795818; called by muse, mutect2
- PCDH9 | c.628T>C p.L210= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV60594206; called by muse, mutect2, varscan2
- PCDHB15 | c.2157G>A p.A719= | Silent (SNP) | VAF 18/266 reads (7%) | catalogued as rs1226095911, COSV50880401, COSV99178803; called by muse, mutect2
- PCDHB16 | c.2124C>T p.F708= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as rs1554282453, COSV53361764; called by muse, mutect2
- PCMTD2 | c.1017C>A p.R339= | Silent (SNP) | VAF 13/249 reads (5%) | called by muse, mutect2
- PDZK1 | c.39C>G p.S13= | Silent (SNP) | VAF 15/260 reads (6%) | catalogued as rs150154026; called by muse, mutect2
- PGBD2 | c.1293G>T p.V431= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV61401262; called by muse, mutect2
- PIGQ | c.1242C>T p.I414= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1288071771, COSV50322517; called by muse, mutect2, varscan2
- PLA2G4D | c.730C>T p.L244= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs770965549, COSV51824205; called by muse, mutect2, varscan2
- PLOD3 | c.423G>A p.E141= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56186027, COSV99778354; called by muse, mutect2, varscan2
- POLG | c.1722G>T p.R574= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV51525626; called by muse, mutect2
- PSMC3 | c.123C>T p.I41= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs574933431, COSV54083229; called by muse, mutect2
- RAB6B | c.318G>A p.K106= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs200359535, COSV53315958; called by muse, mutect2, varscan2
- RABGAP1 | c.2973T>A p.V991= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV65381097; called by muse, mutect2, varscan2
- RBBP8NL | c.1905G>A p.R635= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV53349041; called by muse, mutect2
- RNASE10 | c.237C>A p.G79= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV60518385; called by muse, mutect2, varscan2
- SEMA4G | c.1179G>A p.L393= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs760713409, COSV52972479; called by mutect2, varscan2
- SLC25A22 | c.405G>T p.G135= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SLC6A2 | c.216C>T p.F72= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV54914595; called by muse, mutect2, varscan2
- SNX9 | c.891C>T p.L297= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1004186841, COSV67586211; called by muse, mutect2, varscan2
- SPTY2D1 | c.984T>A p.S328= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV60475699; called by muse, mutect2
- TIE1 | c.1047G>T p.R349= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV65251607; called by muse, mutect2
- TMPRSS3 | c.1269C>T p.I423= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs372469227; ClinVar: uncertain significance; called by muse, mutect2
- TSHZ3 | c.2872C>A p.R958= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV53664159, COSV53683978; called by muse, mutect2
- TTBK1 | c.846C>G p.T282= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV52497194; called by muse, mutect2, varscan2
- URB2 | c.2637G>A p.K879= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV51055154; called by muse, mutect2, varscan2
- WT1 | c.1146T>A p.A382= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV60084848; called by muse, mutect2
- ZC3H14 | c.2052C>T p.Y684= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV51774011; called by muse, mutect2
- ZFP30 | c.588A>G p.R196= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV63623185; called by muse, mutect2
- ZFP57 | c.183A>T p.L61= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as COSV65307125; called by muse, mutect2
- ZMYND8 | c.2355C>T p.V785= (on ENST00000311275 / NM_001363741.2; = p.V805= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV53696985; called by muse, mutect2
- ZMYND8 | c.1740C>G p.V580= (on ENST00000311275 / NM_001363741.2; = p.V600= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV53697006; called by muse, mutect2
- ZNF410 | c.1212C>T p.S404= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs780352236, COSV57912384; called by muse, mutect2, varscan2
- AC024940.1 | n.2828C>T | RNA (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240126689 G>T | 3'Flank (SNP) | VAF 11/114 reads (10%) | catalogued as COSV56229041; called by muse, mutect2, varscan2
- CR1 | c.487+12127G>A | Intron (SNP) | VAF 15/153 reads (10%) | catalogued as rs780838328; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516153 C>T | 5'Flank (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53065361; called by muse, mutect2, varscan2
- OBSCN | c.11660-2607C>A | Intron (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- PPFIA1 | c.264+11537_264+11571del | Intron (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel
- RNF217-AS1 | n.2734T>C | RNA (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SNORD116-3 | n.79C>T | RNA (SNP) | VAF 16/190 reads (8%) | catalogued as rs1008816231; called by muse, mutect2
